Somatic mutation profile of tumor specimen TCGA-DJ-A2PO-01A (aliquot TCGA-DJ-A2PO-01A-21D-A19J-08) from TCGA case TCGA-DJ-A2PO, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 54.9 years (20,058 days).
Specimen TCGA-DJ-A2PO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46eeb8c7-26b7-4ded-827a-4ef9cab9bd6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2PO-10A (Blood Derived Normal), aliquot TCGA-DJ-A2PO-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/174b0e7f-2d92-4989-bf22-c7d80451780b

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP30 | c.482A>T p.Q161L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV63518847; called by muse, mutect2, varscan2
- PAWR | c.722A>G p.Y241C | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.789); catalogued as rs1318306900, COSV60924691; called by muse, mutect2, varscan2
- SETBP1 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV56334543; called by muse, mutect2
- ADCK2 | c.1068G>C p.L356= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV50783227; called by muse, mutect2, varscan2
